CCDI case PBBUGF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/46623be6-85fd-4654-a526-b4dd86f6b5f6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Myofibromatosis: ICD-O-3 morphology code: 8824/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 5.2 years (1,891 days).

Biospecimens (4 samples)
- Sample 0DHFKZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHFLS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DHFN3, 0DHPXO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
